CCDI case PBCFGF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/0d6017c0-efbf-40cb-a2b5-e418eca6a989

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdoid tumor, NOS: ICD-O-3 morphology code: 8963/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 1.9 years (708 days).

Biospecimens (3 samples)
- Sample 0DRO3I: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRO3V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRQT6: Tissue type: Tumor; Specimen type: Solid Tissue.
